MMRF case MMRF_1211 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/461bd31c-c782-44f7-bd3e-2120d613883c

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 46 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 46.8 years (17,090 days); ISS stage: I; Days to last known disease status: 1,610 days (4.4 years); Days to last follow up: 1,610 days (4.4 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 53 days.
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 64 days; Days to treatment end: 78 days.
   Treatment given: Therapeutic agents: Cyclophosphamide + Dexamethasone + Other; Regimen or line of therapy: First line of therapy; Days to treatment start: 101 days; Days to treatment end: 101 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 127 days; Days to treatment end: 127 days.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -5 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 218 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.1 mg/dL; Immunoglobulin G 5.32 g/L; Immunoglobulin A 0.59 g/L; Immunoglobulin M 0.37 g/L; Beta 2 Microglobulin 3.24 µg/mL; Lactate Dehydrogenase 3.48 µkat/L; Hemoglobin 6.2 mmol/L; Leukocytes 9.1 ×10⁹/L; Absolute Neutrophil 5.4 ×10⁹/L; Platelets 284 ×10⁹/L; Creatinine 188 µmol/L; Blood Urea Nitrogen 15.4 mmol/L; Calcium 2.35 mmol/L; Albumin 37 g/L; Total Protein 6.1 g/dL; Glucose 5.34 mmol/L.
- Day 92 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.64 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.04 mg/dL; Immunoglobulin G 6.71 g/L; Immunoglobulin A 0.61 g/L; Immunoglobulin M 0.42 g/L; Lactate Dehydrogenase 3.53 µkat/L; Hemoglobin 7.38 mmol/L; Leukocytes 8.4 ×10⁹/L; Absolute Neutrophil 5.7 ×10⁹/L; Platelets 238 ×10⁹/L; Creatinine 187 µmol/L; Blood Urea Nitrogen 11.8 mmol/L; Calcium 2.35 mmol/L; Albumin 38 g/L; Total Protein 6 g/dL; Glucose 5.06 mmol/L.
- Day 186 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.59 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.819 mg/dL; Immunoglobulin G 5.66 g/L; Immunoglobulin A 0.2 g/L; Immunoglobulin M 0.07 g/L; Lactate Dehydrogenase 3.43 µkat/L; Hemoglobin 3.97 mmol/L; Leukocytes 7.1 ×10⁹/L; Absolute Neutrophil 4.7 ×10⁹/L; Platelets 181 ×10⁹/L; Creatinine 141 µmol/L; Blood Urea Nitrogen 9.64 mmol/L; Calcium 2.38 mmol/L; Albumin 33 g/L; Total Protein 6 g/dL; Glucose 5.45 mmol/L.
- Day 301 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.56 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.6 mg/dL; Immunoglobulin G 10.6 g/L; Immunoglobulin A 0.84 g/L; Immunoglobulin M 0.16 g/L; Lactate Dehydrogenase 3.5 µkat/L; Hemoglobin 6.51 mmol/L; Leukocytes 7.4 ×10⁹/L; Absolute Neutrophil 5 ×10⁹/L; Platelets 200 ×10⁹/L; Creatinine 167 µmol/L; Blood Urea Nitrogen 11.8 mmol/L; Calcium 2.25 mmol/L; Albumin 39 g/L; Total Protein 6.7 g/dL; Glucose 6.27 mmol/L.
- Day 393 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.44 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.13 mg/dL; Immunoglobulin G 9.83 g/L; Immunoglobulin A 0.93 g/L; Immunoglobulin M 0.42 g/L; Beta 2 Microglobulin 3.4 µg/mL; Lactate Dehydrogenase 2.83 µkat/L; Hemoglobin 6.63 mmol/L; Leukocytes 8.1 ×10⁹/L; Absolute Neutrophil 5.4 ×10⁹/L; Platelets 190 ×10⁹/L; Creatinine 159 µmol/L; Blood Urea Nitrogen 10.7 mmol/L; Calcium 2.25 mmol/L; Albumin 38 g/L; Total Protein 6.7 g/dL; Glucose 5.01 mmol/L.
- Day 498 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.67 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.89 mg/dL; Immunoglobulin G 11.2 g/L; Immunoglobulin A 1.43 g/L; Immunoglobulin M 0.58 g/L; Lactate Dehydrogenase 5.15 µkat/L; Hemoglobin 6.39 mmol/L; Leukocytes 9.3 ×10⁹/L; Absolute Neutrophil 6 ×10⁹/L; Platelets 183 ×10⁹/L; Creatinine 180 µmol/L; Blood Urea Nitrogen 8.93 mmol/L; Calcium 2.08 mmol/L; Albumin 37 g/L; Total Protein 6.1 g/dL; Glucose 4.79 mmol/L.
- Day 584 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.67 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.49 mg/dL; Immunoglobulin G 11.3 g/L; Immunoglobulin A 1.4 g/L; Immunoglobulin M 0.64 g/L; Lactate Dehydrogenase 2.65 µkat/L; Hemoglobin 7.07 mmol/L; Leukocytes 8.4 ×10⁹/L; Absolute Neutrophil 5.5 ×10⁹/L; Platelets 203 ×10⁹/L; Creatinine 173 µmol/L; Blood Urea Nitrogen 10.7 mmol/L; Calcium 2.2 mmol/L; Albumin 40 g/L; Total Protein 6.5 g/dL; Glucose 5.45 mmol/L.
- Day 672 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.85 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.4 mg/dL; Immunoglobulin G 12.1 g/L; Immunoglobulin A 1.9 g/L; Immunoglobulin M 0.73 g/L; Hemoglobin 7.01 mmol/L; Leukocytes 10.2 ×10⁹/L; Absolute Neutrophil 6.3 ×10⁹/L; Platelets 198 ×10⁹/L.
- Day 770 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.13 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.76 mg/dL; Immunoglobulin G 16.7 g/L; Immunoglobulin A 2.35 g/L; Immunoglobulin M 0.74 g/L; Lactate Dehydrogenase 2.55 µkat/L; Hemoglobin 7.13 mmol/L; Leukocytes 8.9 ×10⁹/L; Absolute Neutrophil 5.6 ×10⁹/L; Platelets 199 ×10⁹/L; Creatinine 178 µmol/L; Blood Urea Nitrogen 11.8 mmol/L; Calcium 2.3 mmol/L; Albumin 41 g/L; Total Protein 7.4 g/dL; Glucose 5.5 mmol/L.
- Day 861 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.1 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.04 mg/dL; Immunoglobulin G 16 g/L; Immunoglobulin A 2.2 g/L; Immunoglobulin M 1.16 g/L; Lactate Dehydrogenase 2.68 µkat/L; Hemoglobin 7.32 mmol/L; Leukocytes 10.8 ×10⁹/L; Absolute Neutrophil 6.7 ×10⁹/L; Platelets 233 ×10⁹/L; Creatinine 164 µmol/L; Blood Urea Nitrogen 11.4 mmol/L; Calcium 2.3 mmol/L; Albumin 42 g/L; Total Protein 7.3 g/dL; Glucose 6.16 mmol/L.
- Day 956 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 5 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.69 mg/dL; Immunoglobulin G 16.2 g/L; Immunoglobulin A 2.07 g/L; Immunoglobulin M 0.97 g/L; Lactate Dehydrogenase 2.9 µkat/L; Hemoglobin 6.57 mmol/L; Leukocytes 9.5 ×10⁹/L; Absolute Neutrophil 6.2 ×10⁹/L; Platelets 239 ×10⁹/L; Creatinine 179 µmol/L; Blood Urea Nitrogen 9.28 mmol/L; Calcium 2.25 mmol/L; Albumin 42 g/L; Total Protein 7.4 g/dL; Glucose 6.38 mmol/L.
- Day 1,050 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.7 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.67 mg/dL; Immunoglobulin G 15.2 g/L; Immunoglobulin A 2.12 g/L; Immunoglobulin M 0.88 g/L; Lactate Dehydrogenase 2.52 µkat/L; Hemoglobin 7.19 mmol/L; Leukocytes 10.5 ×10⁹/L; Absolute Neutrophil 7 ×10⁹/L; Platelets 195 ×10⁹/L; Creatinine 164 µmol/L; Blood Urea Nitrogen 10.7 mmol/L; Calcium 2.28 mmol/L; Albumin 38 g/L; Total Protein 6.9 g/dL; Glucose 6 mmol/L.
- Day 1,233 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.36 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.68 mg/dL; Immunoglobulin G 15.7 g/L; Immunoglobulin A 2.32 g/L; Immunoglobulin M 1.03 g/L; Beta 2 Microglobulin 2.9 µg/mL; Lactate Dehydrogenase 2.38 µkat/L; Hemoglobin 7.87 mmol/L; Leukocytes 9.9 ×10⁹/L; Absolute Neutrophil 6.1 ×10⁹/L; Platelets 206 ×10⁹/L; Creatinine 147 µmol/L; Blood Urea Nitrogen 10.4 mmol/L; Calcium 2.25 mmol/L; Albumin 39 g/L; Total Protein 6.9 g/dL; Glucose 6.38 mmol/L.
- Day 1,372 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.68 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.1 mg/dL; Immunoglobulin G 16.1 g/L; Immunoglobulin A 2.6 g/L; Immunoglobulin M 1.09 g/L; Lactate Dehydrogenase 3.08 µkat/L; Hemoglobin 7.75 mmol/L; Leukocytes 10.8 ×10⁹/L; Absolute Neutrophil 6.9 ×10⁹/L; Platelets 205 ×10⁹/L; Creatinine 146 µmol/L; Blood Urea Nitrogen 9.64 mmol/L; Calcium 2.35 mmol/L; Albumin 41 g/L; Total Protein 7.4 g/dL; Glucose 5.56 mmol/L.
- Day 1,491 (ECOG 0): Serum Free Immunoglobulin Light Chain, Kappa 5.08 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.39 mg/dL; Immunoglobulin G 15.7 g/L; Immunoglobulin A 2.8 g/L; Immunoglobulin M 1.02 g/L; Lactate Dehydrogenase 2.85 µkat/L; Hemoglobin 7.81 mmol/L; Leukocytes 8.5 ×10⁹/L; Absolute Neutrophil 5.3 ×10⁹/L; Platelets 188 ×10⁹/L; Creatinine 148 µmol/L; Blood Urea Nitrogen 10.7 mmol/L; Calcium 2.3 mmol/L; Albumin 40 g/L; Total Protein 7.4 g/dL; Glucose 6.11 mmol/L.
- Day 1,610 (ECOG 0): Serum Free Immunoglobulin Light Chain, Kappa 5.43 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.31 mg/dL; Immunoglobulin G 16.5 g/L; Immunoglobulin A 2.95 g/L; Immunoglobulin M 1.13 g/L; Lactate Dehydrogenase 2.6 µkat/L; Hemoglobin 7.75 mmol/L; Leukocytes 10.3 ×10⁹/L; Absolute Neutrophil 6.2 ×10⁹/L; Platelets 193 ×10⁹/L; Creatinine 156 µmol/L; Blood Urea Nitrogen 12.5 mmol/L; Calcium 2.23 mmol/L; Albumin 38 g/L; Total Protein 7.1 g/dL; Glucose 5.83 mmol/L.

Other clinical attributes
- Day -5: Weight: 89 kg; Height: 182 cm.

Family history
- Relative with cancer history: yes; Relationship type: Sibling; Relationship primary diagnosis: Kidney Cancer.

Biospecimens (1 sample)
- Sample MMRF_1211_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -5 days.
